Somatic mutation profile of tumor specimen MP2PRT-PAVEBR-TMP1-A (aliquot MP2PRT-PAVEBR-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVEBR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,376 days).
Specimen MP2PRT-PAVEBR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff0a8cd9-3387-473f-a688-d82711c38c36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVEBR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVEBR-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03f8f898-3d4e-45f8-ae54-8630819ddc8f

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Translation Start Site 1, Nonsense Mutation 1, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL3A1 | c.3401G>A p.G1134E | Missense Mutation (SNP) | VAF 220/503 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58597624; called by muse, mutect2, varscan2
- FRMPD4 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 184/198 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66216068; called by muse, mutect2, varscan2
- FUBP3 | c.1606C>T p.Q536* | Nonsense Mutation (SNP) | VAF 259/621 reads (42%) | catalogued as COSV60516265; called by muse, mutect2, varscan2
- KIAA1217 | c.2737G>A p.V913M | Missense Mutation (SNP) | VAF 308/799 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as rs368934080; called by muse, mutect2, varscan2
- VHL | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 494/1118 reads (44%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs578091032, COSV56542939, COSV99078436; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF2B | c.1452T>G p.A484= | Silent (SNP) | VAF 257/599 reads (43%) | catalogued as COSV99274555; called by muse, mutect2, varscan2
- RGS6 | c.*250G>T | 3'UTR (SNP) | VAF 174/379 reads (46%) | called by muse, mutect2, varscan2
